Somatic mutation profile of tumor specimen HCM-BROD-0448-C15-06A (aliquot HCM-BROD-0448-C15-06A-11D-A79N-36) from HCMI case HCM-BROD-0448-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 78.6 years (28,714 days).
Specimen HCM-BROD-0448-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Pleural Effusion; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9f38b063-4b23-4900-8afa-6b701371d789.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0448-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0448-C15-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1555578-1a47-4406-a567-59122abcb639

The open-access MAF lists 117 somatic variants for this specimen: 90 protein-altering or splice-affecting, 24 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 24, Nonsense Mutation 4, 5'UTR 1, Splice Site 1, Intron 1, Frame Shift Ins 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 51/357 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- CA6 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as rs184168475; called by muse, mutect2
- CCDC173 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754874295; called by muse, mutect2, varscan2
- CD1C | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as COSV100939479; called by muse, mutect2, varscan2
- CDKN2A | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 93/751 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as CD994409, COSV58703816; called by muse, mutect2, varscan2
- CDKN2A | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 94/749 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs878853646, CD111993, CD961883, CM960271, COSV58683653, COSV58684450, COSV58705440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD7 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 93/464 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.182); catalogued as COSV101418023; called by muse, mutect2, varscan2
- COQ8A | c.1715C>T p.S572F | Missense Mutation (SNP) | VAF 57/482 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV62010629; called by muse, mutect2, varscan2
- CP | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 62/363 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs758399451, COSV52831503; called by muse, mutect2, varscan2
- CPZ | c.833G>A p.R278H (on ENST00000360986 / NM_001014447.3; = p.R267H on NM_003652.3) | Missense Mutation (SNP) | VAF 79/555 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs773276230; called by muse, mutect2, varscan2
- CTNNA2 | c.2575-1G>T p.X859_splice (on ENST00000402739 / NM_001282597.3; = p.X811_splice on NM_004389.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 22/116 reads (19%) | catalogued as COSV58131567; called by muse, mutect2, varscan2
- CTNND1 | c.1960C>T p.R654* (on ENST00000399050 / NM_001085458.2; = p.R648* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 47/287 reads (16%) | catalogued as COSV100650349; called by muse, mutect2, varscan2
- DOK4 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1277329947, COSV54673701; called by muse, varscan2
- EN1 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 126/728 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs1180306542; called by mutect2, varscan2
- GRM5 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 42/271 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100555154; called by muse, mutect2, varscan2
- GTF2H4 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 100/526 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV104389948; called by muse, mutect2, varscan2
- GZMK | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 26/483 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.63); catalogued as rs202051718, COSV50244331; called by muse, mutect2
- KCNQ3 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV66463149; called by muse, mutect2, varscan2
- LRRK1 | c.5743G>A p.V1915I | Missense Mutation (SNP) | VAF 83/428 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as rs775588013, COSV52628754; called by muse, mutect2, varscan2
- MYF5 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 62/509 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as rs1289442350, COSV57356011; called by muse, mutect2, varscan2
- NRDC | c.691A>G p.T231A | Missense Mutation (SNP) | VAF 44/375 reads (12%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as rs768764407, COSV61405177; called by muse, mutect2, varscan2
- PCDHB6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.068); catalogued as rs782110772, COSV50714923, COSV50738202; called by muse, varscan2
- PER2 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as rs745547801, COSV99612764; called by muse, varscan2
- PHKG2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 71/542 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs532137455, COSV60312800; called by muse, mutect2, varscan2
- POSTN | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.11); catalogued as rs370902652; called by muse, mutect2, varscan2
- PPP1CA | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 102/483 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as rs1273880415, COSV56702423; called by muse, mutect2, varscan2
- RBFOX3 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 41/347 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1477183313; called by muse, mutect2, varscan2
- RHOBTB3 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.358); catalogued as rs763502813, COSV101183270; called by muse, varscan2
- RSF1 | c.1424C>T p.S475F | Missense Mutation (SNP) | VAF 55/301 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as rs751215835, COSV57837366; called by muse, mutect2, varscan2
- SLC66A2 | c.443A>G p.Q148R | Missense Mutation (SNP) | VAF 61/418 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs760461464; called by muse, mutect2, varscan2
- SLC6A9 | c.1928G>A p.R643H (on ENST00000360584 / NM_201649.4; = p.R589H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs141553063; called by muse, mutect2, varscan2
- STAP2 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 46/380 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs145893074; called by muse, mutect2, varscan2
- TMEM151B | c.1471C>T p.R491C | Missense Mutation (SNP) | VAF 66/864 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.764); catalogued as rs1363984774; called by muse, mutect2
- TREM1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 45/267 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs1018046222, COSV55148255; called by muse, mutect2, varscan2
- WDR45B | c.919G>A p.A307T | Missense Mutation (SNP) | VAF 31/292 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753663465, COSV101124421, COSV66408248; called by muse, mutect2, varscan2
- ZC3H3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 79/769 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs776395632, COSV52794799; called by muse, mutect2, varscan2
- ZHX2 | c.2395G>A p.G799R | Missense Mutation (SNP) | VAF 84/463 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs752370410, COSV100073974, COSV58712967; called by muse, mutect2, varscan2
- ZP3 | c.476C>A p.P159H (on ENST00000394857 / NM_001110354.2; = p.P108H on NM_007155.6) | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV60633713; called by muse, mutect2
- ACAD9 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2
- AIM2 | c.883G>A p.G295R | Missense Mutation (SNP) | VAF 59/445 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- AP1G2 | c.844A>G p.S282G | Missense Mutation (SNP) | VAF 57/392 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARID1B | c.3277_3283del p.C1093Kfs*22 | Frame Shift Del (DEL) | VAF 36/328 reads (11%) | called by mutect2, pindel, varscan2
- ATP2A1 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AUTS2 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 56/1044 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- CFH | c.3026A>C p.K1009T | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.371); called by muse, mutect2
- CHSY3 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 46/768 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.043); called by muse, mutect2
- CNPPD1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 57/610 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.916); called by muse, mutect2
- DDX43 | c.1583A>G p.K528R | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2
- ECM2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENTPD1 | c.1099A>G p.M367V | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2
- FAM71A | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- FLACC1 | c.1254T>A p.C418* | Nonsense Mutation (SNP) | VAF 46/256 reads (18%) | called by muse, mutect2, varscan2
- FSIP2 | c.12028T>C p.F4010L | Missense Mutation (SNP) | VAF 9/194 reads (5%) | SIFT tolerated (0.67); PolyPhen benign (0.302); called by muse, mutect2
- GABRG3 | c.489G>T p.L163F | Missense Mutation (SNP) | VAF 27/218 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GDF6 | c.938G>A p.W313* | Nonsense Mutation (SNP) | VAF 22/510 reads (4%) | called by muse, mutect2
- GNMT | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 100/711 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GRHL2 | c.1246T>C p.F416L | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK2 | c.2352G>T p.Q784H | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- HCN1 | c.1845C>A p.N615K | Missense Mutation (SNP) | VAF 48/538 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.258); called by muse, mutect2
- HMCN1 | c.12232C>T p.P4078S | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IBTK | c.2289dup p.C764Mfs*6 | Frame Shift Ins (INS) | VAF 18/169 reads (11%) | called by mutect2, pindel, varscan2
- IGDCC3 | c.1349A>C p.N450T | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2
- KCNH4 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2
- KCNH4 | c.601A>C p.K201Q | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- KIF2B | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 26/468 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2
- MAP4K1 | c.2177A>T p.D726V | Missense Mutation (SNP) | VAF 108/431 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- MAPK4 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 70/496 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL24 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- MFSD11 | c.938T>C p.L313S | Missense Mutation (SNP) | VAF 62/433 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- MMS22L | c.3241A>T p.K1081* | Nonsense Mutation (SNP) | VAF 49/247 reads (20%) | called by muse, mutect2, varscan2
- MYCBP2 | c.13414G>A p.E4472K (on ENST00000357337; = p.E4510K on NM_015057.5) | Missense Mutation (SNP) | VAF 46/322 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR2J1 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 39/445 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.265); called by muse, mutect2
- PPP2R3C | c.803A>C p.N268T | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SH3BP5 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 74/443 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SMCO2 | c.917C>A p.T306K | Missense Mutation (SNP) | VAF 46/385 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- SOX17 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 124/909 reads (14%) | SIFT tolerated (0.94); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SPTBN5 | c.2258A>G p.D753G | Missense Mutation (SNP) | VAF 53/647 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SSC5D | c.4256A>T p.N1419I | Missense Mutation (SNP) | VAF 46/790 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- TMEM132E | c.2647G>A p.G883S (on ENST00000321639; = p.G973S on NM_001304438.2) | Missense Mutation (SNP) | VAF 32/738 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.286); called by muse, mutect2
- TPSD1 | c.676T>C p.S226P | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRAV23DV6 | c.205G>T p.G69W | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRIL | c.2254G>T p.G752C | Missense Mutation (SNP) | VAF 68/830 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); called by muse, mutect2
- TRIO | c.1932G>C p.E644D | Missense Mutation (SNP) | VAF 38/519 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2
- TSPYL5 | c.479C>A p.P160H | Missense Mutation (SNP) | VAF 101/702 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ULK4 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.34); called by muse, mutect2
- USH1G | c.710G>A p.G237E | Missense Mutation (SNP) | VAF 57/810 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- VANGL2 | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 22/225 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- VARS2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 70/482 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF846 | c.268C>G p.L90V | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- ZXDB | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 114/833 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); called by muse, varscan2
- ASRGL1 | c.420G>T p.V140= | Silent (SNP) | VAF 71/392 reads (18%) | called by muse, mutect2, varscan2
- BMP3 | c.366C>T p.T122= | Silent (SNP) | VAF 26/436 reads (6%) | called by muse, mutect2
- CFHR1 | c.897G>T p.V299= | Silent (SNP) | VAF 32/350 reads (9%) | called by muse, mutect2, varscan2
- CHD8 | c.204T>G p.P68= | Silent (SNP) | VAF 23/434 reads (5%) | called by muse, mutect2
- DIDO1 | c.633C>T p.G211= | Silent (SNP) | VAF 47/695 reads (7%) | catalogued as rs1240560188, COSV56621860; called by muse, mutect2
- EXT1 | c.1104C>T p.F368= | Silent (SNP) | VAF 30/636 reads (5%) | called by muse, mutect2
- IL12RB1 | c.708C>T p.P236= | Silent (SNP) | VAF 55/395 reads (14%) | called by muse, mutect2, varscan2
- ITSN1 | c.894C>T p.V298= | Silent (SNP) | VAF 34/418 reads (8%) | called by muse, mutect2
- KIAA1109 | c.1917C>T p.N639= | Silent (SNP) | VAF 31/175 reads (18%) | catalogued as rs373929838; called by muse, mutect2, varscan2
- LRRC41 | c.795C>T p.L265= | Silent (SNP) | VAF 44/369 reads (12%) | catalogued as rs1366456257; called by muse, mutect2, varscan2
- LYNX1-SLURP2 | c.216C>T p.S72= | Silent (SNP) | VAF 49/431 reads (11%) | catalogued as rs1263992797; called by muse, mutect2, varscan2
- MYH3 | c.4932C>T p.L1644= | Silent (SNP) | VAF 18/359 reads (5%) | called by muse, mutect2
- NCAM1 | c.1746C>T p.Y582= (on ENST00000316851 / NM_181351.5; = p.Y572= on NM_000615.7) | Silent (SNP) | VAF 103/402 reads (26%) | catalogued as rs3741072; called by muse, mutect2, varscan2
- NR4A3 | c.576C>T p.H192= | Silent (SNP) | VAF 81/644 reads (13%) | catalogued as rs761297484; called by muse, mutect2, varscan2
- NRXN1 | c.2658C>T p.G886= | Silent (SNP) | VAF 75/352 reads (21%) | catalogued as rs752920557, COSV58468328; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PAPLN | c.483C>T p.H161= | Silent (SNP) | VAF 28/439 reads (6%) | catalogued as rs774419908; called by muse, mutect2
- SCN8A | c.2775C>T p.S925= | Silent (SNP) | VAF 45/631 reads (7%) | called by muse, mutect2
- SCN9A | c.1545C>T p.H515= | Silent (SNP) | VAF 49/421 reads (12%) | called by muse, mutect2, varscan2
- SLC47A1 | c.1677G>T p.V559= | Silent (SNP) | VAF 21/267 reads (8%) | called by muse, mutect2
- TAS2R30 | c.306C>T p.L102= | Silent (SNP) | VAF 34/430 reads (8%) | called by muse, mutect2
- THOC2 | c.2613A>G p.K871= | Silent (SNP) | VAF 62/260 reads (24%) | called by muse, mutect2, varscan2
- TNK2 | c.2733G>A p.P911= | Silent (SNP) | VAF 51/435 reads (12%) | catalogued as rs373899133; called by muse, mutect2, varscan2
- TTC30B | c.999T>C p.Y333= | Silent (SNP) | VAF 21/496 reads (4%) | catalogued as COSV101282756; called by muse, mutect2
- UBE2QL1 | c.333A>G p.A111= | Silent (SNP) | VAF 54/461 reads (12%) | called by muse, varscan2
- PDPN | c.-158G>A | 5'UTR (SNP) | VAF 67/628 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF6 | c.3746-2524G>A | Intron (SNP) | VAF 22/404 reads (5%) | catalogued as rs909060982; called by muse, mutect2
- SEPTIN3 | chr22:41972084 C>T | 5'Flank (SNP) | VAF 37/322 reads (11%) | catalogued as rs1448813820; called by muse, mutect2, varscan2
